Somatic mutation profile of tumor specimen TARGET-10-PARPDP-09A (aliquot TARGET-10-PARPDP-09A-01D) from TARGET case TARGET-10-PARPDP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.9 years (6,184 days).
Specimen TARGET-10-PARPDP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a8dd3bb-e9c3-46f9-8333-7ccf2be1c77a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPDP-10A (Blood Derived Normal), aliquot TARGET-10-PARPDP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56ec1860-02ed-4874-b03f-fb987a58e364

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFHR1 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as COSV57628268; called by muse, mutect2
- CGN | c.3335G>A p.R1112H | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374749068; called by muse, mutect2, varscan2
- FAT1 | c.12035C>T p.T4012M | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs752997628, COSV71673299; called by muse, mutect2, varscan2
- PXDN | c.3776C>T p.P1259L | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs369587687, COSV99070649; called by muse, mutect2, varscan2
- ZNF582 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1328731578; called by muse, mutect2, varscan2
- NBEA | c.6850A>G p.N2284D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RTL1 | c.3168C>T p.I1056= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- AGAP2 | c.2857+20G>A | Intron (SNP) | VAF 32/76 reads (42%) | catalogued as rs746808977; called by muse, mutect2, varscan2
- SLC35B1 | c.216-26T>C | Intron (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
